Somatic mutation profile of tumor specimen 0DTB8W from CCDI case PBCJKF, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Neoplasm, malignant; Tissue or organ of origin: Abdomen, NOS; Age at diagnosis: 2.4 years (865 days).
Specimen 0DTB8W: Tissue type: Tumor; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 43dafa61-4eaa-401b-9330-3acbd5805312.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DTB8N (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/68bf597a-c472-4c1d-a42d-718c5e712e0b

The open-access MAF lists 36 somatic variants for this specimen: 23 protein-altering or splice-affecting, 4 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 20, 5'UTR 4, Silent 4, 5'Flank 2, In Frame Del 2, 3'UTR 2, Nonsense Mutation 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FGFR4 | c.1648G>C p.V550L | Missense Mutation (SNP) | VAF 352/406 reads (87%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV52800715, COSV52802492, COSV52804538; called by muse, mutect2, varscan2
- ARHGEF25 | c.1286G>C p.R429P | Missense Mutation (SNP) | VAF 160/561 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV99678370; called by muse, mutect2, varscan2
- CIART | c.488G>A p.R163H | Missense Mutation (SNP) | VAF 127/333 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs782449723, COSV51745318; called by muse, mutect2, varscan2
- H3C7 | c.363G>A p.M121I | Missense Mutation (SNP) | VAF 101/312 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.015); catalogued as rs1331046387; called by muse, mutect2, varscan2
- HBS1L | c.662C>G p.T221R | Missense Mutation (SNP) | VAF 135/349 reads (39%) | SIFT tolerated (0.52); PolyPhen benign (0.091); catalogued as COSV63201776; called by muse, mutect2, varscan2
- NRXN1 | c.2210C>A p.T737K | Missense Mutation (SNP) | VAF 122/405 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); catalogued as COSV58468499; called by muse, mutect2, varscan2
- RNFT2 | c.161C>T p.A54V | Missense Mutation (SNP) | VAF 217/662 reads (33%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs1325951658; called by muse, mutect2, varscan2
- A3GALT2 | c.508C>A p.Q170K | Missense Mutation (SNP) | VAF 109/203 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- ACVR1 | c.767_772del p.M256_L257del | In Frame Del (DEL) | VAF 89/393 reads (23%) | called by mutect2, pindel, varscan2
- CCDC181 | c.469C>A p.Q157K | Missense Mutation (SNP) | VAF 12/381 reads (3%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- CFAP99 | c.411C>G p.S137R (on ENST00000506607; = p.S690R on NM_001193282.3) | Missense Mutation (SNP) | VAF 133/315 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- CHL1 | c.1750G>A p.E584K (on ENST00000397491 / NM_001253387.1; = p.E600K on NM_006614.4) | Missense Mutation (SNP) | VAF 98/339 reads (29%) | SIFT tolerated (0.32); PolyPhen benign (0.205); called by muse, mutect2, varscan2
- DCC | c.4118C>G p.T1373S | Missense Mutation (SNP) | VAF 110/267 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- KCNJ12 | c.365C>T p.P122L | Missense Mutation (SNP) | VAF 146/684 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.755); called by muse, mutect2, varscan2
- KCNJ3 | c.1216A>T p.I406F | Missense Mutation (SNP) | VAF 168/591 reads (28%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- LHX8 | c.556T>C p.C186R | Missense Mutation (SNP) | VAF 131/315 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PCDHGB6 | c.885T>G p.D295E | Missense Mutation (SNP) | VAF 123/407 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.344); called by muse, mutect2, varscan2
- PLCH1 | c.3778G>C p.A1260P (on ENST00000340059 / NM_001130960.2; = p.A1252P on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 168/569 reads (30%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); called by muse, mutect2, varscan2
- PRAMEF11 | c.345G>A p.W115* | Nonsense Mutation (SNP) | VAF 84/260 reads (32%) | called by muse, mutect2
- RESF1 | c.4504G>C p.V1502L | Missense Mutation (SNP) | VAF 131/444 reads (30%) | SIFT tolerated (0.26); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- SLC19A2 | c.1127_1129del p.A376del | In Frame Del (DEL) | VAF 127/335 reads (38%) | called by pindel, varscan2
- SLC19A2 | c.1118T>C p.I373T | Missense Mutation (SNP) | VAF 141/336 reads (42%) | SIFT tolerated (0.65); PolyPhen benign (0.216); called by muse, varscan2
- TTN | c.97313G>T p.R32438I (on ENST00000591111; = p.R25014I on NM_003319.4) | Missense Mutation (SNP) | VAF 148/567 reads (26%) | PolyPhen benign (0.031); called by muse, mutect2, varscan2
- ST6GAL2 | c.159G>A p.P53= | Silent (SNP) | VAF 95/333 reads (29%) | catalogued as rs1219472459, COSV100868341; called by muse, mutect2, varscan2
- TNR | c.468C>T p.N156= | Silent (SNP) | VAF 192/444 reads (43%) | catalogued as rs765569785, COSV54901502; called by muse, mutect2
- TNRC18 | c.333C>T p.H111= | Silent (SNP) | VAF 141/535 reads (26%) | catalogued as rs373753964; ClinVar: likely benign; called by muse, mutect2, varscan2
- ZNF571 | c.501T>G p.S167= | Silent (SNP) | VAF 132/297 reads (44%) | called by muse, mutect2, varscan2
- AC131160.1 | c.*28C>T | 3'UTR (SNP) | VAF 118/427 reads (28%) | catalogued as rs763006882; called by muse, mutect2, varscan2
- ADGRD1 | c.*21G>T | 3'UTR (SNP) | VAF 91/287 reads (32%) | called by muse, mutect2, varscan2
- C1QTNF3 | c.-52T>G | 5'UTR (SNP) | VAF 109/306 reads (36%) | called by muse, mutect2, varscan2
- EIF3I | chr1:32222295 C>A | 5'Flank (SNP) | VAF 114/280 reads (41%) | called by muse, mutect2, varscan2
- MIA2 | chr14:39266810 G>C | 5'Flank (SNP) | VAF 17/69 reads (25%) | called by muse, mutect2, varscan2
- OR1F12 | n.322G>T | RNA (SNP) | VAF 173/426 reads (41%) | called by muse, mutect2, varscan2
- P3H1 | c.-6G>T | 5'UTR (SNP) | VAF 87/194 reads (45%) | called by muse, mutect2, varscan2
- PCDHB13 | c.-40A>G | 5'UTR (SNP) | VAF 62/235 reads (26%) | called by muse, mutect2, varscan2
- ZNF335 | c.-5A>G | 5'UTR (SNP) | VAF 113/419 reads (27%) | called by muse, mutect2, varscan2
